Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1X5, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1X5-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – right breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the right breast.

ICD-0-3

carcinoma, infiltrating duct, nos 8500/3
Site: breast, nos C50.9
for 4/12

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in 10-75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO. Positive reaction in invasive carcinoma cells
(Score = 3+)

Compliance validated by:

Examination performed on:

Macroscopic description:

Right breast sized 23 x 18 x 4 cm removed along with axillary tissues sized 12 x 8 x 3.5 cm and a skin flap of 21 x 11 cm. Weight 700 g.

Tumour sized 4.5 x 3.5 x 3 cm found on the boundary of outer quadrants, located 4.2 cm from the outer boundary, 0.5 cm from the base and 1.7 cm from the skin.

Microscopic description:

Carcinoma invasivum (partim signet ring cell carcinoma) - NHG2 (3+3+1/7 mitoses/10 HPF - visual area 0.55mm).

Glandular tissue showing parenchymal atrophy. Axillary lymph nodes:

Metastases et micrometastases carcinomatosae in lymphonodis (No XIV/XVI). Infiltratio capsulae lymphonodorum et telae perinodalis. Emboliae carcinomatosae vasorum.

Histopathological diagnosis:

Carcinoma invasivum mammae dextrae.

Metastases et micrometastases carcinomatosae in lymphonodis axillae (No XIV/XVI). (NHG2; pT2; pN3a). Final diagnosis to be given after supplementary tests.

Compliance validated by:

Examination performed on:

[page 2 of 2]
Examination: Histopathological examination

page 2 / 2

Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on

Examination result/Final Histopathological diagnosis:

Carcinoma ductale invasivum mammae dextrae. NHG2, pT2, pN3a.

Invasive ductal carcinoma of the right breast NHG2, pT2, pN3a.

Immunophenotype: CK7-, CK 5/6-, GCDFP-15-, E-cadherin+, PAS+

Compliance validated L, .

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 646a3ab7-8127-4bf7-94ff-e7f2636bdea5 (TCGA-D8-A1X5.449F70F0-DFE1-40F9-879D-43283CFAF525.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).